Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5503, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5503-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of PSA value of 18.4. The patient also has a history of biopsy on [REDACTED]. This biopsy reveals: poorly-differentiated prostatic adenocarcinoma, Gleason score 5+4 = 9 in the left apex of the prostate and Gleason score 4+5 = 9 in the left mid and left base of the prostate. The patient also has a history of [REDACTED].

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

TCGA - EJ - 5503

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF MALIGNANCY IN ELEVEN LYMPH NODES (0/11).

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF MALIGNANCY IN TEN LYMPH NODES (0/10).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 8 (5 + 3), WITH TERTIARY COMPONENT OF GLEASON GRADE 4.
- B. CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT SIDES AND HAS A GREATEST NODULAR DIAMETER OF 1.6 CM.
- C. CARCINOMA INVOLVES APPROXIMATELY 40% OF THE EXAMINED PROSTATE BY VOLUME.
- D. FOCAL EXTRAPROSTATIC EXTENSION IS PRESENT AT THE LEFT ANTERIOR BASE (BLOCK 3T) AND THE LEFT POSTERIOR BASE (BLOCKS 3NN AND 3RR).
- E. BILATERAL SEMINAL VESICLES AND VASA DEFERENTIA ARE FREE OF TUMOR.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
- G. TUMOR IS WITHIN 0.1 mm OF THE RESECTION MARGIN AT THE LEFT ANTERIOR BASE (BLOCK 3T).
- H. PERINEURAL INVASION IS PRESENT.
- I. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- J. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS PRESENT.
- K. PATHOLOGIC TNM STAGE: pT3a N0 MX.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 18.4
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	5
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	60%
WEIGHT OF PROSTATE:	48.24gm
TUMOR SIZE:	Maximum dimension: 1.6 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Multifocal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	21
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file e3524628-631b-447b-8556-9f33eacf163f (TCGA-EJ-5503.81CA6538-6023-4E21-BD59-0B248E5642AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).